Somatic mutation profile of cancer-model specimen HCM-CSHL-0728-C25-85A (3D Organoid, passage 4; aliquot HCM-CSHL-0728-C25-85A-01D-A82I-36), derived from the primary tumor of HCMI case HCM-CSHL-0728-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: GX; Age at diagnosis: 54.8 years (20,008 days).
Specimen HCM-CSHL-0728-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fabfbfde-12bc-429b-8e78-23f90de546e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0728-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0728-C25-10A-01D-A82I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0c76fc9-0313-4569-8ccb-8a54ca7f1a9a

The open-access MAF lists 55 somatic variants for this specimen: 38 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, Intron 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 143/318 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.8603C>T p.A2868V | Missense Mutation (SNP) | VAF 239/533 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs569768217; called by muse, mutect2, varscan2
- C18orf21 | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 143/276 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1487801036; called by muse, mutect2, varscan2
- CDH13 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 255/593 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV99223670; called by muse, mutect2
- CNNM4 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 357/750 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs765710051; called by muse, mutect2, varscan2
- ENTPD2 | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 423/846 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1474327912; called by muse, mutect2, varscan2
- ERICH3 | c.4316G>A p.R1439Q | Missense Mutation (SNP) | VAF 251/489 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as COSV58602391; called by muse, mutect2, varscan2
- FOXL3 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 188/452 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72563063; called by muse, mutect2
- GPR50 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs1288793743, COSV54436783; called by muse, mutect2
- GRIK1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 289/595 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs140284503; called by muse, mutect2, varscan2
- KDM6A | c.1827C>G p.Y609* | Nonsense Mutation (SNP) | VAF 322/322 reads (100%) | catalogued as COSV65042737, COSV65046157; called by muse, mutect2, varscan2
- MAP2K2 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 312/720 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs730880509; ClinVar: likely benign; called by muse, mutect2
- MATN4 | c.1475G>A p.R492H (on ENST00000372754; = p.R451H on NM_003833.4) | Missense Mutation (SNP) | VAF 409/818 reads (50%) | PolyPhen possibly damaging (0.49); catalogued as rs142628816; called by muse, mutect2, varscan2
- NGEF | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 314/626 reads (50%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.92); catalogued as rs754227975; called by muse, mutect2, varscan2
- PCDHA13 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 238/838 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56515710; called by muse, mutect2, varscan2
- PCDHA5 | c.1203G>T p.K401N | Missense Mutation (SNP) | VAF 38/720 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV100972242; called by muse, mutect2
- RFX1 | c.1864G>A p.V622I | Missense Mutation (SNP) | VAF 161/365 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs746973928; called by muse, mutect2, varscan2
- RXFP3 | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 23/947 reads (2%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as rs895958014, COSV57508534; called by muse, mutect2
- SLC12A8 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 243/549 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs780279352; called by muse, mutect2, varscan2
- SLC38A8 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 275/578 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs767383422, COSV55308554; called by muse, mutect2, varscan2
- SMG9 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 168/345 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54213315; called by muse, mutect2, varscan2
- SOHLH2 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 131/684 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as COSV58521783; called by muse, mutect2, varscan2
- TSPAN14 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 240/484 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199964121, COSV59369313; called by muse, mutect2, varscan2
- ZNF804B | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 151/302 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs760398588; called by muse, mutect2, varscan2
- ANKFN1 | c.2973G>T p.K991N (on ENST00000653862; = p.K844N on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CES1 | c.893_900delinsG p.T298Rfs*2 | Frame Shift Del (DEL) | VAF 192/468 reads (41%) | called by pindel, varscan2*
- FLI1 | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 246/366 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GGN | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 406/1237 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRID2IP | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 310/669 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- HNRNPUL1 | c.573-19_602del p.X191_splice | Splice Site (DEL) | VAF 20/220 reads (9%) | called by mutect2, pindel
- IQGAP1 | c.2992T>G p.S998A | Missense Mutation (SNP) | VAF 214/433 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- L3HYPDH | c.41A>T p.D14V | Missense Mutation (SNP) | VAF 426/969 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCBP3 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 186/438 reads (42%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1488G>T p.E496D | Missense Mutation (SNP) | VAF 250/704 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- PLEKHM1 | c.1668G>C p.E556D | Missense Mutation (SNP) | VAF 516/1027 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRMT6 | c.440A>T p.E147V | Missense Mutation (SNP) | VAF 296/653 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TNS2 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 328/658 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF865 | c.1712T>A p.I571N | Missense Mutation (SNP) | VAF 484/935 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ADCY8 | c.69G>T p.P23= | Silent (SNP) | VAF 108/1023 reads (11%) | called by muse, mutect2, varscan2
- ADGRV1 | c.17106G>A p.K5702= | Silent (SNP) | VAF 64/229 reads (28%) | called by muse, mutect2, varscan2
- CADPS | c.984C>A p.P328= | Silent (SNP) | VAF 52/120 reads (43%) | called by mutect2, varscan2
- CEACAM4 | c.432C>T p.N144= | Silent (SNP) | VAF 152/511 reads (30%) | catalogued as rs781815366, COSV55732941; called by muse, mutect2, varscan2
- COL11A2 | c.1905C>T p.P635= (on ENST00000341947 / NM_080680.3; = p.P528= on NM_080679.2) | Silent (SNP) | VAF 327/682 reads (48%) | called by muse, mutect2, varscan2
- DRD5 | c.333G>A p.A111= | Silent (SNP) | VAF 210/298 reads (70%) | catalogued as COSV58578285; called by muse, varscan2
- FAM114A1 | c.612C>T p.A204= | Silent (SNP) | VAF 217/504 reads (43%) | catalogued as rs747803554; called by muse, mutect2, varscan2
- FOXD3 | c.615G>A p.E205= | Silent (SNP) | VAF 112/723 reads (15%) | called by muse, mutect2, varscan2
- FUT6 | c.969G>A p.E323= | Silent (SNP) | VAF 207/851 reads (24%) | called by muse, mutect2, varscan2
- GDPD5 | c.672C>T p.L224= | Silent (SNP) | VAF 235/538 reads (44%) | catalogued as rs776619262, COSV61130019; called by muse, mutect2, varscan2
- LGSN | c.762C>T p.V254= | Silent (SNP) | VAF 64/240 reads (27%) | catalogued as rs764275316; called by muse, mutect2, varscan2
- RHCE | c.1011G>T p.L337= | Silent (SNP) | VAF 115/264 reads (44%) | catalogued as COSV99604327; called by muse, mutect2, varscan2
- SCN7A | c.4071G>A p.L1357= | Silent (SNP) | VAF 156/337 reads (46%) | called by muse, mutect2, varscan2
- SFMBT2 | c.567T>C p.G189= | Silent (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
- ZNF8 | c.807C>T p.N269= | Silent (SNP) | VAF 159/329 reads (48%) | catalogued as rs762713712, COSV52189351; called by muse, mutect2, varscan2
- GRIA2 | c.2406+418C>A | Intron (SNP) | VAF 28/68 reads (41%) | catalogued as rs754720061, COSV99645534; called by muse, mutect2, varscan2
- UNC13B | c.761+4518A>G | Intron (SNP) | VAF 75/193 reads (39%) | called by muse, mutect2, varscan2
